Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q5, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q5-01A (Primary Tumor).

[page 1 of 4]
	8/3/11	

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

Thyroid nodule FNA consistent with papillary thyroid carcinoma.

Specimens Submitted:

- 1: Delphian node (fs)
- 2: Left tracheal node (fs)
- 3: Left low jugular node (fs)
- 4: Total thyroidectomy
- 5: Additional left jugular node

DIAGNOSIS:

1. Delphian node (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus: 0.3 cm.
Extranodal extension is not identified

ICD-0-3

Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
8/3/11

2. Left tracheal node (fs):

Lymph Node Dissection:

Benign fibroadipose tissue
No lymphoid tissue identified. The specimen is entirely submitted.

3. Left low jugular node (fs):

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 4
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 2.1cm.
Size of the largest metastatic focus: 0.5 cm.
Extranodal extension is not identified

4. Total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Tumor Necrosis:

[page 2 of 4]
Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 4 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

5. Additional left jugular node:

Lymph Node Dissection:

Benign fibroadipose tissue

No lymphoid tissue identified. The specimen is entirely submitted

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

MD.
*** Report Electronically Signed Out ***

Gross Description:

M.D.

1) The specimen is received fresh for intraoperative consultation, labeled "Delphian node". It consists of one piece of tan pink soft tissue, measuring 0.8 x 0.8 x 0.3 cm. One lymph node is identified, measuring 0.5 cm in greatest dimension. The lymph node is entirely submitted for frozen section.

Summary of sections:

FSC-frozen section control

M.D.

[page 3 of 4]
2) The specimen is received fresh for intraoperative consultation labeled "left tracheal node". It consists of one piece of tan pink soft tissue, measuring 0.8 x 0.6 x 0.6 cm. Lymph node is not identified. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC-frozen section control

J.D.

3) The specimen is received fresh for intraoperative consultation labeled "left low jugular node". It consists of one piece of tan pink soft tissue, measuring 2.0 x 2.0 x 0.8 cm. One lymph node is identified, measuring 1.2 cm in greatest dimension. The specimen is entirely submitted for frozen section and permanent section.

Summary of sections:

FSC-frozen section control , bisected lymph node

U-remaining tissue

P.A.

4). The specimen is received in formalin, labeled "total thyroidectomy, stitch at left lobe of thyroid" and consists of a 22.5 g thyroid with a suture marking the left lobe. The right lobe measures 4 x 2.5 x 1.5 cm , the left lobe measures 4.3 x 2.7 x 2.5 cm with an anteriorly attached 3.5 x 1.5 x 1.5 cm portion of muscle tissue and the isthmus measures 2.5 x 2 x 0.7 cm. Superiorly attached to the isthmus is a 2.2 x 1.1 x 0.1 cm pyramidal lobe. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 4 x 2.7 x 2.5 cm ovoid, tan-pink, lobular, firm nodule in the left lobe which abuts both the anterior and posterior capsule. Sections through the remaining tissue reveal red-tan, meaty cut surfaces. A portion of the specimen is previously sent for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RL - right lobe

LL - left lobe

PL - pyramidal lobe

IS - isthmus

5). The specimen is received in formalin, labeled "additional left jugular node" and consists of a 1 x 0.8 x 0.3 cm aggregate of yellow-tan to brown-tan, lobulated fibroadipose tissue with no lymph nodes grossly identified. The specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Delphian node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left tracheal node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Left low jugular node (fs)

Block	Sect. Site	PCs
1	FSC	1
1	U	1

Part 4: Total thyroidectomy

Block	Sect. Site	PCs
-------	------------	-----

[page 4 of 4]
5	IS	9
21	LL	21
2	PL	7
13	RL	15

Part 5: Additional left jugular node

Block	Sect. Site	PCs
1	U	10

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Delphian node (fs): Metastatic carcinoma
Permanent Diagnosis: Same
2. Frozen Section Diagnosis: Left tracheal node (fs): Benign fibroadipose tissue
Permanent Diagnosis: Same
3. Frozen Section Diagnosis: Left low jugular node (fs): Metastatic carcinoma
Permanent Diagnosis: Same

Source: NCI Genomic Data Commons file 6d68b6f6-1efa-450e-bb36-cbdf93f50575 (TCGA-DJ-A2Q5.5291CCC7-0571-48D7-B523-7B0F05C8749D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).